Somatic mutation profile of tumor specimen TCGA-E1-A7YW-01A (aliquot TCGA-E1-A7YW-01A-11D-A34J-08) from TCGA case TCGA-E1-A7YW, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 28.9 years (10,571 days).
Specimen TCGA-E1-A7YW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bea425ec-fd3e-43f0-8670-9cb10a9e7449.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7YW-10A (Blood Derived Normal), aliquot TCGA-E1-A7YW-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ca9777f-7b4e-4cce-a01c-fb69bb91a68f

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 12, Silent 8, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 41/95 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 49/55 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DDIAS | c.1573A>T p.N525Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV100231146; called by muse, mutect2, varscan2
- FAM83B | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs778588613, COSV100173938, COSV100174318, COSV60920027; called by muse, mutect2, varscan2
- FLG | c.4318T>G p.S1440A | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV100911459, COSV100912116; called by muse, mutect2, varscan2
- KHDRBS3 | c.371A>G p.N124S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs778404555, COSV63424194; called by muse, mutect2, varscan2
- MYO1F | c.1376G>C p.S459T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); catalogued as COSV100596599; called by muse, mutect2, varscan2
- PAH | c.770G>A p.G257D | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs62642908, CM010966, CM973039, COSV100187912; ClinVar: not provided; called by muse, mutect2
- PJVK | c.591A>T p.K197N | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.741); catalogued as COSV100910481; called by muse, mutect2, varscan2
- PSMD2 | c.817A>C p.N273H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs767466862, COSV100031681; called by muse, mutect2, varscan2
- TCF12 | c.647_648insTGGT p.P217Gfs*8 | Frame Shift Ins (INS) | VAF 31/109 reads (28%) | catalogued as COSV99977144; called by mutect2, pindel, varscan2
- ZNF32 | c.650A>G p.Y217C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1400929811, COSV100986485; called by muse, mutect2, varscan2
- ZNF772 | c.943A>G p.I315V | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (0.956); catalogued as rs1383202276, COSV100582804; called by muse, mutect2
- ATRX | c.3322del p.S1108Hfs*10 | Frame Shift Del (DEL) | VAF 83/144 reads (58%) | called by mutect2, pindel, varscan2
- CDK5RAP1 | c.1405_1406dup p.F470Afs*8 (on ENST00000357886 / NM_001365728.1; = p.F456Afs*8 on NM_016082.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 44/134 reads (33%) | called by mutect2, pindel, varscan2
- ERC2 | c.2151C>T p.D717= | Silent (SNP) | VAF 16/169 reads (9%) | catalogued as rs530440071, COSV99883416; called by muse, mutect2
- FAM199X | c.189C>T p.H63= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV101534161; called by muse, mutect2
- FBXO31 | c.1266G>A p.E422= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV100291371; called by muse, mutect2, varscan2
- KCNT1 | c.339G>A p.V113= (on ENST00000488444; = p.V132= on NM_020822.3) | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as COSV99705562; called by muse, mutect2, varscan2
- MAN2B2 | c.198C>T p.R66= | Silent (SNP) | VAF 60/126 reads (48%) | catalogued as rs779997292, COSV53454200; called by muse, mutect2, varscan2
- RHCE | c.525C>T p.F175= | Silent (SNP) | VAF 63/136 reads (46%) | catalogued as rs376509301; called by muse, mutect2, varscan2
- RIMS2 | c.4425G>A p.P1475= (on ENST00000666250 / NM_001348490.2; = p.P1046= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as rs143698299, COSV51705007; called by muse, mutect2
- THBS4 | c.765A>C p.I255= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as COSV100644249; called by muse, mutect2, varscan2
